TCGA case TCGA-HC-A9TE — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c51ccff8-2502-40e1-b130-fe655c119169

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 64.5 years (23,543 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC clinical T: T2c; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N0; Primary gleason grade: Pattern 5; Secondary gleason grade: Pattern 4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Gleason score: 9.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 7; Tumor level prostate: Apex / Middle / Base; Zone of origin prostate: Overlapping/multiple zones.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Leuprolide Acetate; Days to treatment start: 216 days; Days to treatment end: 417 days (1.1 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 364 days; Days to treatment end: 417 days (1.1 years); Treatment dose: 7,020 cGy; Treatment outcome: Stable Disease; Number of fractions: 39; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Biochemical Recurrence.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Biochemical Recurrence.

Follow-up (5 entries)
- Day 13 (initial diagnosis): Days to imaging: 13 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Day 16 (initial diagnosis): Days to imaging: 16 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: No Evidence of Extraprostatic Extension.
- Days to follow up: 134 days; Disease response: With Tumor.
- Day 216 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 216 days.
- Days to follow up: 587 days (1.6 years); Disease response: With Tumor.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.064 ng/mL (day 134).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HC-A9TE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 50 mg.
  Slide TCGA-HC-A9TE-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-HC-A9TE-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HC-A9TE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Zone of origin: Overlapping / Multiple Zones; Method initial path diagnosis: Transurethral resection (TURBT); Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: No; Lymph nodes examined: Yes; Treatment outcome first course: Partial Remission/Response; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: No.
- Tumor levels: Tumor level: Apex; Tumor level: Middle; Tumor level: Base.
- Stage record, Psa: PSA most recent results: 0.064.
- Stage record, Gleason grading: Gleason pattern primary: 5; Gleason pattern secondary: 4; Gleason pattern tertiary: 3.
- Drug treatment: Pharmaceutical therapy drug name: Eligard.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; New tumor event diagnosis indicator: Yes; New tumor event type: Biochemical evidence of disease; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; Progression after hormone treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 587 days; disease-specific survival: no event (censored), 587 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 216 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HC-A9TE-01A-11D-A41J-01): tumor purity 0.55, ploidy 3.09, whole-genome doublings 1.
